Somatic mutation profile of tumor specimen ALCH-B025-TTP1-A (aliquot ALCH-B025-TTP1-A-1-0-D-A673-36) from ALCHEMIST case ALCH-B025, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.3 years (19,849 days).
Specimen ALCH-B025-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91d29604-5726-459a-a2a1-7673adf1225a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B025-NB1-A (Blood Derived Normal), aliquot ALCH-B025-NB1-A-1-0-D-A673-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3ee8e670-ddc7-40d2-80e0-8822b366032b

The open-access MAF lists 40 somatic variants for this specimen: 32 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 5, Frame Shift Del 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 62/390 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- COLEC12 | c.135T>G p.I45M | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV68370651, COSV68372657; called by muse, mutect2, varscan2
- DCAF12L1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.206); catalogued as rs907259332, COSV100948469, COSV64421371; called by mutect2, varscan2
- KIF19 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs748686424; called by muse, mutect2, varscan2
- KLHDC7B | c.809G>A p.R270H (on ENST00000395676; = p.R911H on NM_138433.5) | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.263); catalogued as rs1311390942; called by mutect2, varscan2
- KRTAP13-4 | c.96C>G p.S32R | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV61879126; called by muse, mutect2, varscan2
- LY75-CD302 | c.5120T>C p.I1707T | Missense Mutation (SNP) | VAF 22/190 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776215920; called by muse, mutect2, varscan2
- MAX | c.200C>A p.A67D | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786202340; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRC2B | c.2310G>A p.M770I | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1343812210; called by muse, mutect2, varscan2
- XKR5 | c.1760G>A p.G587D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.2); catalogued as rs746373015; called by muse, mutect2, varscan2
- YLPM1 | c.4711C>T p.Q1571* | Nonsense Mutation (SNP) | VAF 39/216 reads (18%) | catalogued as rs1421060103; called by muse, varscan2
- ZDBF2 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.125); catalogued as COSV65623519; called by muse, mutect2, varscan2
- ZNF836 | c.1814C>A p.T605N | Missense Mutation (SNP) | VAF 27/235 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs745677194; called by muse, mutect2, varscan2
- C16orf96 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCBLD1 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM174C | c.238T>G p.F80V | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- GAD2 | c.1084C>T p.H362Y | Missense Mutation (SNP) | VAF 21/199 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HPGD | c.454dup p.C152Lfs*19 | Frame Shift Ins (INS) | VAF 108/561 reads (19%) | called by mutect2, pindel, varscan2
- ICE1 | c.6586A>G p.I2196V | Missense Mutation (SNP) | VAF 43/375 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- LAT | c.109G>T p.D37Y | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- LYPD8 | c.544T>C p.S182P | Missense Mutation (SNP) | VAF 29/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- MFSD6L | c.458T>A p.F153Y | Missense Mutation (SNP) | VAF 41/271 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MIDEAS | c.1493C>A p.S498* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2
- OR1E2 | c.228del p.T77Qfs*22 | Frame Shift Del (DEL) | VAF 20/188 reads (11%) | called by mutect2, varscan2
- OR5AN1 | c.850C>G p.P284A | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- PHF10 | c.792del p.E264Dfs*16 | Frame Shift Del (DEL) | VAF 44/222 reads (20%) | called by mutect2, pindel, varscan2
- SLC2A9 | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 25/323 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- SLTM | c.2210A>G p.D737G | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SNX29 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMCO1 | c.38G>T p.R13I | Missense Mutation (SNP) | VAF 58/216 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ZNF233 | c.1619C>T p.T540I | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF442 | c.1237G>C p.A413P | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- ADSS1 | c.558G>T p.L186= | Silent (SNP) | VAF 18/170 reads (11%) | called by muse, mutect2
- GAD2 | c.675A>G p.R225= | Silent (SNP) | VAF 39/279 reads (14%) | called by muse, mutect2, varscan2
- GMPPA | c.93G>C p.V31= | Silent (SNP) | VAF 42/309 reads (14%) | called by muse, mutect2, varscan2
- SFTPB | c.723G>A p.V241= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- TACC2 | c.1041C>T p.P347= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- HAL | c.1833+12C>T | Intron (SNP) | VAF 52/330 reads (16%) | called by muse, mutect2, varscan2
- TCEANC2 | c.*8199A>G | 3'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs1356049508; called by mutect2, varscan2
- TUBB7P | n.1245C>T | RNA (SNP) | VAF 30/178 reads (17%) | catalogued as rs782123391; called by muse, mutect2, varscan2
